FM case AD521 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/d2379204-00a7-4963-b3ef-108370a8300f

Female, 47.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the cervix uteri. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
